Somatic mutation profile of cancer-model specimen HCM-BROD-0926-C16-85B (3D Organoid, passage 6; aliquot HCM-BROD-0926-C16-85B-01D-A88G-36), derived from the primary tumor of HCMI case HCM-BROD-0926-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 30.9 years (11,285 days).
Specimen HCM-BROD-0926-C16-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b82be083-494b-418f-92df-6424179e84ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0926-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0926-C16-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bdd6cbe-f859-48c0-be1b-f910404a63be

The open-access MAF lists 152 somatic variants for this specimen: 114 protein-altering or splice-affecting, 35 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 35, Frame Shift Del 5, Nonsense Mutation 5, In Frame Del 2, Intron 1, 3'Flank 1, Frame Shift Ins 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 319/320 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 127/257 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs769866607; called by muse, mutect2, varscan2
- ADGRB3 | c.3274G>A p.A1092T | Missense Mutation (SNP) | VAF 107/268 reads (40%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.908); catalogued as rs781253779, COSV53253456; called by muse, mutect2, varscan2
- APOB | c.6973del p.I2325Lfs*6 | Frame Shift Del (DEL) | VAF 60/530 reads (11%) | catalogued as COSV51952357; called by pindel, varscan2
- APOB | c.1755G>C p.Q585H | Missense Mutation (SNP) | VAF 70/594 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV51933716; called by muse, mutect2, varscan2
- CNTNAP5 | c.463G>T p.V155L | Missense Mutation (SNP) | VAF 298/298 reads (100%) | SIFT tolerated (0.81); PolyPhen benign (0.357); catalogued as rs1389539692; called by muse, mutect2, varscan2
- DHX37 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 177/343 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.26); catalogued as rs764393311, COSV58137311; called by muse, mutect2, varscan2
- DPY19L4 | c.2056T>A p.F686I | Missense Mutation (SNP) | VAF 71/419 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs776555307; called by muse, mutect2, varscan2
- FAT3 | c.6143A>G p.E2048G | Missense Mutation (SNP) | VAF 194/657 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV99961836; called by muse, mutect2, varscan2
- FILIP1 | c.1154A>C p.K385T | Missense Mutation (SNP) | VAF 63/426 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52729888; called by muse, mutect2, varscan2
- GAD2 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 155/236 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs182756899; called by muse, mutect2, varscan2
- H4C6 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 75/421 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66685668; called by muse, mutect2, varscan2
- LCT | c.3320C>T p.T1107M | Missense Mutation (SNP) | VAF 367/367 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs937987859, COSV51551568, COSV51559414; called by muse, mutect2, varscan2
- LRP4 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 184/184 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs138301752; called by muse, mutect2, varscan2
- MEF2C | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 40/577 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60929723, COSV60936642; called by muse, mutect2
- MUC19 | c.20T>A p.L7H | Missense Mutation (SNP) | VAF 191/333 reads (57%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.046); catalogued as COSV67127071; called by muse, mutect2, varscan2
- ORAI1 | c.26del p.P9Rfs*55 | Frame Shift Del (DEL) | VAF 206/421 reads (49%) | catalogued as rs1555322471; called by mutect2, pindel, varscan2
- PEX5 | c.1553G>A p.R518H (on ENST00000420616; = p.R510H on NM_000319.5) | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs146183061; called by muse, mutect2, varscan2
- PIP5K1B | c.500del p.L167Cfs*21 | Frame Shift Del (DEL) | VAF 54/171 reads (32%) | catalogued as COSV55247823, COSV55256034; called by mutect2, pindel, varscan2
- PPP1R3A | c.982A>C p.I328L | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV52876584; called by muse, mutect2
- RGS7BP | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 73/543 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV61834991; called by muse, mutect2, varscan2
- RPS6KA6 | c.869T>C p.L290P | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.517); catalogued as COSV53116777, COSV53128576; called by muse, mutect2
- RTN1 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 321/478 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.366); catalogued as rs1196838903, COSV99954549; called by muse, mutect2, varscan2
- SLC25A46 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 243/547 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV63507323; called by muse, mutect2, varscan2
- TMEM150B | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 121/497 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1033483663, COSV58593651; called by muse, mutect2, varscan2
- TMEM272 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 186/386 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs763643952; called by muse, mutect2, varscan2
- UBE2O | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 97/411 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as rs770134258, COSV100084939; called by muse, mutect2, varscan2
- UBE2Q2 | c.194C>G p.S65C | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV51194884; called by muse, mutect2, varscan2
- VDAC3 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 206/353 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs751469875, COSV99195118; called by muse, mutect2, varscan2
- XYLT1 | c.2362G>A p.V788I | Missense Mutation (SNP) | VAF 37/652 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.041); catalogued as rs201348549; called by muse, mutect2
- YBX1 | c.49_57del p.A17_A19del | In Frame Del (DEL) | VAF 69/478 reads (14%) | catalogued as rs770070516; called by mutect2, varscan2
- ZFHX3 | c.10537_10569del p.S3513_G3523del | In Frame Del (DEL) | VAF 93/318 reads (29%) | catalogued as rs1567506139; called by mutect2, pindel, varscan2
- ZNF99 | c.2330G>A p.R777K | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV68055925, COSV68056592; called by muse, mutect2, varscan2
- ABHD16B | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 332/563 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.041); called by muse, varscan2
- ADAM12 | c.633G>T p.K211N | Missense Mutation (SNP) | VAF 39/532 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.138); called by muse, mutect2
- ADAMTS18 | c.669T>G p.N223K | Missense Mutation (SNP) | VAF 31/701 reads (4%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2
- ADGRD2 | c.355C>G p.L119V | Missense Mutation (SNP) | VAF 34/442 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2
- ALG13 | c.2614C>G p.Q872E | Missense Mutation (SNP) | VAF 49/346 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALK | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 121/525 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- AQP9 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARID5B | c.2794C>A p.Q932K | Missense Mutation (SNP) | VAF 236/237 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- ATF6B | c.107C>A p.S36Y | Missense Mutation (SNP) | VAF 116/390 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- C2CD3 | c.2125G>A p.G709S | Missense Mutation (SNP) | VAF 176/417 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- C2orf16 | c.4078G>A p.A1360T | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CBLB | c.1612A>T p.R538* | Nonsense Mutation (SNP) | VAF 38/151 reads (25%) | called by muse, mutect2, varscan2
- CBY2 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 23/647 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.028); called by muse, mutect2
- CCL3 | c.41C>A p.T14N | Missense Mutation (SNP) | VAF 87/533 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- CDH1 | c.1009-1_1009insTTTG p.X337_splice | Splice Site (INS) | VAF 145/288 reads (50%) | called by mutect2, pindel*, varscan2*
- CDH8 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 244/466 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHRDL2 | c.481C>G p.P161A | Missense Mutation (SNP) | VAF 25/562 reads (4%) | SIFT tolerated (1); PolyPhen possibly damaging (0.654); called by muse, mutect2
- CMTM1 | c.197_198dup p.T67* (on ENST00000457188 / NM_181269.3; = p.T184* on NM_052999.4) | Frame Shift Ins (INS) | VAF 113/294 reads (38%) | called by mutect2, pindel, varscan2
- CMYA5 | c.9922G>A p.V3308I | Missense Mutation (SNP) | VAF 62/383 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- COL24A1 | c.1637C>A p.P546H | Missense Mutation (SNP) | VAF 167/169 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- DIO3 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 52/632 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- DUOX1 | c.3695A>G p.Y1232C | Missense Mutation (SNP) | VAF 34/463 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- EIF1B | c.94C>G p.H32D | Missense Mutation (SNP) | VAF 71/233 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- FAM135B | c.4106C>T p.A1369V | Missense Mutation (SNP) | VAF 62/479 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAR1 | c.653A>T p.E218V | Missense Mutation (SNP) | VAF 64/247 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FAT3 | c.5281G>C p.D1761H | Missense Mutation (SNP) | VAF 46/629 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FETUB | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 151/670 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- FGA | c.377C>G p.T126S | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GCM2 | c.1015A>G p.K339E | Missense Mutation (SNP) | VAF 126/299 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- GPR61 | c.686G>T p.C229F | Missense Mutation (SNP) | VAF 16/544 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- GRIK4 | c.1691T>C p.L564P | Missense Mutation (SNP) | VAF 20/566 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- IKBKB | c.383A>T p.D128V | Missense Mutation (SNP) | VAF 55/356 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INTS7 | c.1127A>G p.E376G | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- KCNC1 | c.782T>A p.L261H | Missense Mutation (SNP) | VAF 37/297 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KCND1 | c.467C>G p.A156G | Missense Mutation (SNP) | VAF 29/511 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- KLK9 | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 71/418 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LCN1 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 18/176 reads (10%) | called by muse, mutect2
- LMOD2 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 32/371 reads (9%) | called by muse, mutect2
- MBD3L4 | c.29C>G p.P10R | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); called by mutect2, varscan2
- MCF2 | c.987A>T p.K329N | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2
- MECOM | c.353T>C p.L118S (on ENST00000468789 / NM_001105078.4; = p.L306S on NM_004991.4) | Missense Mutation (SNP) | VAF 250/773 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- MEIS2 | c.746G>T p.S249I (on ENST00000561208 / NM_170675.5; = p.S236I on NM_002399.3) | Missense Mutation (SNP) | VAF 161/161 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- MMRN1 | c.2789T>C p.M930T | Missense Mutation (SNP) | VAF 92/400 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MPPED2 | c.878G>C p.G293A | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2
- MUC12 | c.12184A>G p.T4062A (on ENST00000379442; = p.T3919A on NM_001164462.1) | Missense Mutation (SNP) | VAF 34/1054 reads (3%) | SIFT deleterious (0.03); called by muse, mutect2
- MYO10 | c.5545C>T p.P1849S | Missense Mutation (SNP) | VAF 238/488 reads (49%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- NIBAN1 | c.953A>T p.N318I | Missense Mutation (SNP) | VAF 21/272 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2
- NID1 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 205/206 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- OR2A7 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 45/307 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- OR5AN1 | c.772T>G p.F258V | Missense Mutation (SNP) | VAF 34/694 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- OSTN | c.230A>G p.E77G | Missense Mutation (SNP) | VAF 117/535 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTUD7A | c.2044_2087del p.D682Hfs*188 (on ENST00000307050 / NM_001382637.1; = p.D675Hfs*188 on NM_130901.3) | Frame Shift Del (DEL) | VAF 102/175 reads (58%) | called by mutect2, pindel, varscan2
- PDE10A | c.1773G>C p.M591I | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PDS5B | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 24/538 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); called by muse, mutect2
- PGAP1 | c.1524C>G p.N508K | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- PIEZO2 | c.7886A>G p.E2629G | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PIEZO2 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 201/201 reads (100%) | called by muse, mutect2, varscan2
- PITPNM1 | c.3397G>C p.A1133P | Missense Mutation (SNP) | VAF 65/606 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- PKHD1L1 | c.6887del p.P2296Lfs*2 | Frame Shift Del (DEL) | VAF 39/196 reads (20%) | called by mutect2, pindel*, varscan2
- PNPLA2 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- PRKG2 | c.227G>T p.C76F | Missense Mutation (SNP) | VAF 11/296 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.113); called by muse, mutect2
- RLF | c.2048A>C p.K683T | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF180 | c.190G>C p.V64L | Missense Mutation (SNP) | VAF 134/357 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SFPQ | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 160/720 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by mutect2, varscan2
- SNX19 | c.2017G>A p.V673I | Missense Mutation (SNP) | VAF 140/437 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SOCS7 | c.584G>A p.S195N | Missense Mutation (SNP) | VAF 141/913 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.961); called by muse, varscan2
- SPTA1 | c.958G>T p.V320L | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); called by muse, mutect2
- SRGAP1 | c.102C>G p.C34W | Missense Mutation (SNP) | VAF 85/262 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STKLD1 | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 36/386 reads (9%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2
- TAF1 | c.4316A>G p.Y1439C (on ENST00000373790 / NM_138923.4; = p.Y1460C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/130 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TERB2 | c.9A>T p.Q3H | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- TGS1 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 42/228 reads (18%) | called by muse, mutect2, varscan2
- THSD7A | c.2773G>T p.V925F | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- TLX3 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 369/858 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TMEM174 | c.383C>G p.P128R | Missense Mutation (SNP) | VAF 24/770 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM235 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 58/414 reads (14%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- TRPM4 | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 128/417 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC8 | c.701A>G p.E234G (on ENST00000338104 / NM_001288781.1; = p.E218G on NM_144596.4) | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.738); called by muse, mutect2
- TUBE1 | c.219G>C p.L73F | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- VEGFA | c.355G>C p.E119Q (on ENST00000523873 / NM_001171623.1; = p.E299Q on NM_003376.6) | Missense Mutation (SNP) | VAF 117/387 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ZP4 | c.1427C>A p.T476N | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); called by muse, mutect2
- ANKRD55 | c.834C>A p.A278= | Silent (SNP) | VAF 17/495 reads (3%) | called by muse, mutect2
- BCL3 | c.1086C>T p.A362= | Silent (SNP) | VAF 211/313 reads (67%) | called by muse, mutect2, varscan2
- C5 | c.253T>C p.L85= | Silent (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- C6orf141 | c.447G>T p.R149= | Silent (SNP) | VAF 119/487 reads (24%) | called by muse, mutect2, varscan2
- DENND4A | c.4296G>A p.A1432= | Silent (SNP) | VAF 126/370 reads (34%) | catalogued as rs781718938; called by muse, mutect2, varscan2
- FAM47B | c.1045C>T p.L349= | Silent (SNP) | VAF 205/205 reads (100%) | called by muse, mutect2, varscan2
- FNDC8 | c.183C>T p.F61= | Silent (SNP) | VAF 16/222 reads (7%) | catalogued as COSV50100466; called by muse, mutect2
- FZD10 | c.864C>T p.I288= | Silent (SNP) | VAF 249/602 reads (41%) | catalogued as COSV57471949; called by muse, mutect2, varscan2
- GIMD1 | c.24C>T p.I8= | Silent (SNP) | VAF 165/312 reads (53%) | catalogued as rs1405176567; called by muse, mutect2, varscan2
- GSC2 | c.6G>A p.A2= | Silent (SNP) | VAF 246/246 reads (100%) | called by muse, mutect2, varscan2
- HMG20B | c.924C>T p.I308= | Silent (SNP) | VAF 22/376 reads (6%) | catalogued as rs769825871; called by muse, mutect2
- HRNR | c.6576G>A p.S2192= | Silent (SNP) | VAF 356/2042 reads (17%) | catalogued as rs567290240, COSV64260199, COSV64260339; called by muse, mutect2, varscan2
- IDUA | c.1287C>T p.G429= | Silent (SNP) | VAF 111/353 reads (31%) | called by muse, mutect2, varscan2
- KIF1A | c.4404G>T p.T1468= (on ENST00000320389 / NM_001379639.1; = p.T1460= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 344/345 reads (100%) | called by muse, mutect2, varscan2
- KLK9 | c.99C>A p.S33= | Silent (SNP) | VAF 71/422 reads (17%) | called by muse, mutect2, varscan2
- LCMT1 | c.636C>G p.L212= | Silent (SNP) | VAF 192/442 reads (43%) | called by muse, mutect2, varscan2
- LRP6 | c.2013G>A p.V671= | Silent (SNP) | VAF 50/267 reads (19%) | called by muse, mutect2, varscan2
- MCHR2 | c.822C>T p.N274= | Silent (SNP) | VAF 134/383 reads (35%) | called by muse, mutect2, varscan2
- NELFE | c.810C>T p.D270= | Silent (SNP) | VAF 54/738 reads (7%) | called by muse, mutect2
- NOP53 | c.1153C>T p.L385= | Silent (SNP) | VAF 172/720 reads (24%) | called by muse, mutect2
- OSBPL7 | c.873G>A p.L291= | Silent (SNP) | VAF 397/397 reads (100%) | called by muse, mutect2, varscan2
- P2RY8 | c.615G>T p.P205= | Silent (SNP) | VAF 25/530 reads (5%) | catalogued as rs147029517; called by muse, mutect2
- PCDH11X | c.3615C>T p.I1205= | Silent (SNP) | VAF 405/405 reads (100%) | catalogued as rs768994403, COSV53455584, COSV53502052; called by muse, mutect2, varscan2
- PGGHG | c.1668C>A p.G556= | Silent (SNP) | VAF 10/291 reads (3%) | catalogued as rs1423235094; called by muse, mutect2
- PLEKHG6 | c.2145G>A p.E715= | Silent (SNP) | VAF 80/475 reads (17%) | catalogued as rs1044736173; called by muse, mutect2, varscan2
- PPARGC1A | c.789C>A p.T263= | Silent (SNP) | VAF 10/197 reads (5%) | catalogued as COSV99337536; called by muse, mutect2
- PPP1R37 | c.1965C>T p.V655= | Silent (SNP) | VAF 41/515 reads (8%) | called by muse, mutect2
- PRSS54 | c.117C>T p.Y39= | Silent (SNP) | VAF 67/445 reads (15%) | catalogued as rs1414039933, COSV54689347; called by muse, mutect2, varscan2
- STAP1 | c.516G>A p.L172= | Silent (SNP) | VAF 110/110 reads (100%) | called by muse, mutect2, varscan2
- TCHH | c.3399C>T p.R1133= | Silent (SNP) | VAF 86/723 reads (12%) | called by muse, varscan2
- TFDP1 | c.933G>A p.S311= | Silent (SNP) | VAF 113/670 reads (17%) | catalogued as rs147172256, COSV100945671; called by muse, mutect2, varscan2
- TLX3 | c.276G>T p.A92= | Silent (SNP) | VAF 371/860 reads (43%) | catalogued as rs1352133888, COSV51540705; called by muse, mutect2, varscan2
- TMCO6 | c.123C>T p.S41= | Silent (SNP) | VAF 66/390 reads (17%) | catalogued as rs1296832760; called by muse, mutect2, varscan2
- UNCX | c.921G>A p.A307= | Silent (SNP) | VAF 321/321 reads (100%) | catalogued as rs751232846; called by muse, mutect2, varscan2
- ZBTB45 | c.1449C>G p.P483= | Silent (SNP) | VAF 231/624 reads (37%) | called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57621690 A>T | 3'Flank (SNP) | VAF 73/357 reads (20%) | catalogued as rs931317892, COSV54089679; called by muse, mutect2
- KCNQ1 | c.1393+21485T>G | Intron (SNP) | VAF 40/124 reads (32%) | called by muse, mutect2, varscan2
- ZNF81 | c.*683G>A | 3'UTR (SNP) | VAF 134/135 reads (99%) | called by muse, mutect2, varscan2
